Somatic mutation profile of tumor specimen TCGA-06-1806-01A (aliquot TCGA-06-1806-01A-02D-1845-08) from TCGA case TCGA-06-1806, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.4 years (17,296 days).
Specimen TCGA-06-1806-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba494db-8cf5-4506-8c65-a3bd27e42138.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-1806-10B (Blood Derived Normal), aliquot TCGA-06-1806-10B-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e407da3-12c4-4fe6-80cc-d213a72088cb

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATP9B | c.3082A>T p.M1028L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV56946234; called by muse, mutect2, varscan2
- B3GAT1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56995164; called by mutect2, varscan2
- FUT5 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs758815585, COSV53134795; called by muse, mutect2, varscan2
- KAT14 | c.2023A>C p.S675R | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66606711; called by muse, mutect2, varscan2
- LRRIQ1 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs758047410, COSV67826147; called by muse, mutect2, varscan2
- LUM | c.585G>C p.Q195H | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV57127517; called by muse, mutect2, varscan2
- MAPK8IP1 | c.2075A>G p.Q692R | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV53796716; called by muse, mutect2, varscan2
- NHS | c.3565A>G p.M1189V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV66271414; called by muse, mutect2, varscan2
- PCDHB7 | c.2371T>G p.L791V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as COSV50754337; called by muse, mutect2, varscan2
- PTPRJ | c.3667C>T p.R1223C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746784211, COSV69249865; called by muse, mutect2, varscan2
- QSOX2 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs770075933, COSV62393409; called by muse, mutect2, varscan2
- SLCO5A1 | c.2257A>G p.I753V | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV52653864; called by muse, mutect2, varscan2
- SRRD | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV53225562; called by muse, mutect2, varscan2
- MLST8 | c.337del p.D113Tfs*15 | Frame Shift Del (DEL) | VAF 38/173 reads (22%) | called by mutect2, pindel, varscan2
- ANTXR1 | c.6C>T p.A2= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV58009305; called by muse, mutect2, varscan2
- DOT1L | c.2349G>A p.R783= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV67108080; called by muse, mutect2, varscan2
- OR2L3 | c.294T>A p.I98= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as COSV63454477; called by muse, mutect2, varscan2
- SEMG2 | c.1590T>A p.S530= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as COSV65647196; called by muse, mutect2
- TMEM184C | c.213A>G p.L71= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV56853062; called by muse, mutect2, varscan2
- SNORD114-15 | n.26G>A | RNA (SNP) | VAF 18/69 reads (26%) | catalogued as rs752195009; called by muse, mutect2, varscan2
